Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A8W8, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A8W8-01B (Primary Tumor).

Specimen Date/Time:

ICD.O-3
Adenocarcinoma NOS 8140/3
Site ^{CHL} Esophagus, distal third
path C15.5
Esophagus NOS
C15.9
12/3/14

DIAGNOSIS

- (A) DISTAL ESOPHAGUS MASS, BIOPSIES:
INFILTRATING, MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH OVERLAYING
SQUAMOUS MUCOSA.

GROSS DESCRIPTION

- (A) DISTAL ESOPHAGEAL MASS – The specimen consists of multiple pink-tan friable soft tissue fragments, aggregating to 1 x 0.2 x 0.1 cm. Entirely submitted in A.

CLINICAL HISTORY

Esophageal cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by
specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

. These tests have not been

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 832908db-27d1-4cc6-a32c-5a5f1682f90a (TCGA-R6-A8W8.3D93A47C-25F1-4859-A2B5-421F30EA2736.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).